Somatic mutation profile of tumor specimen ALCH-AENO-TTP1-A (aliquot ALCH-AENO-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AENO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.8 years (24,752 days).
Specimen ALCH-AENO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 547d2cf6-dae7-4384-9504-51c1093c08f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENO-NB1-A (Blood Derived Normal), aliquot ALCH-AENO-NB1-A-2-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a458eed4-7cfe-4f73-b866-de8e9c054708

The open-access MAF lists 41 somatic variants for this specimen: 35 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Nonsense Mutation 3, Silent 3, Frame Shift Del 2, Splice Site 2, 3'Flank 2, Splice Region 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+2T>C p.X1010_splice | Splice Site (SNP) | VAF 64/436 reads (15%) | hotspot (GDC flag); catalogued as COSV100577355, COSV59257966, COSV59268376, COSV59269013; called by muse, mutect2, varscan2
- CAMK2B | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs767955476, COSV51660565; called by muse, mutect2
- F2R | c.763C>G p.H255D | Missense Mutation (SNP) | VAF 78/457 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59929401; called by muse, mutect2, varscan2
- GIPC2 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 30/359 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765583476, COSV66127201; called by muse, mutect2
- GNL3L | c.64A>C p.S22R | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs1222250730; called by muse, mutect2
- LTBP4 | c.2776G>A p.E926K (on ENST00000308370 / NM_001042544.1; = p.E889K on NM_003573.2) | Missense Mutation (SNP) | VAF 17/528 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV52584947; called by muse, mutect2
- MAN2B1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 40/524 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765088432; called by muse, mutect2
- NOS1AP | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 58/531 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV62636030; called by muse, mutect2, varscan2
- PDGFRA | c.2323+7G>C | Splice Region (SNP) | VAF 35/340 reads (10%) | catalogued as rs763780833; ClinVar: likely benign; called by muse, mutect2
- PPEF2 | c.1131C>G p.C377W | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV54423635, COSV54427201; called by muse, mutect2
- SLC13A5 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs1477649056; called by muse, mutect2, varscan2
- SWSAP1 | c.2T>G p.M1? (on ENST00000312423; = p.M22R on NM_175871.4) | Translation Start Site (SNP) | VAF 10/102 reads (10%) | PolyPhen benign (0); catalogued as rs1568326643; called by muse, varscan2
- SYNE1 | c.9064C>T p.Q3022* (on ENST00000367255 / NM_182961.4; = p.Q3029* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 38/385 reads (10%) | catalogued as COSV99574852; called by muse, mutect2
- TRDMT1 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs780907376, COSV58320566; called by muse, mutect2, varscan2
- ARHGAP35 | c.3392G>A p.G1131E | Missense Mutation (SNP) | VAF 63/611 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ATP6V1H | c.958A>G p.N320D | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2
- ATXN1L | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 43/526 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC181 | c.851C>A p.T284K | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CDAN1 | c.1745A>C p.Q582P | Missense Mutation (SNP) | VAF 50/638 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- CELF1 | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EGLN3 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 33/330 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FMN1 | c.1110G>C p.L370F | Missense Mutation (SNP) | VAF 18/497 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.026); called by muse, mutect2
- GHR | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 62/966 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- HSPA12B | c.755A>G p.K252R | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.845); called by muse, mutect2
- INSL3 | c.190+2T>G p.X64_splice | Splice Site (SNP) | VAF 43/303 reads (14%) | called by muse, mutect2, varscan2
- KBTBD3 | c.1148T>C p.F383S | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYT1L | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBI1 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 46/518 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.214); called by muse, mutect2
- PCSK6 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2
- POLR3F | c.218T>A p.L73* | Nonsense Mutation (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- SERINC2 | c.15_28del p.G6Afs*63 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- SETD2 | c.7237del p.R2413Gfs*37 | Frame Shift Del (DEL) | VAF 37/312 reads (12%) | called by mutect2, pindel, varscan2
- TTC27 | c.599C>G p.S200* | Nonsense Mutation (SNP) | VAF 15/436 reads (3%) | called by muse, mutect2
- ZNF600 | c.275A>T p.Y92F | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2
- ZNF746 | c.1877T>G p.V626G | Missense Mutation (SNP) | VAF 94/632 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP46A1 | c.48C>T p.F16= | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as rs569975911; called by muse, mutect2
- ITGA2B | c.1095G>A p.P365= | Silent (SNP) | VAF 30/338 reads (9%) | catalogued as rs780507775, COSV99288618; called by muse, mutect2
- XKR3 | c.516T>C p.F172= | Silent (SNP) | VAF 53/586 reads (9%) | called by muse, mutect2
- KAZALD1 | chr10:101067315 G>A | 3'Flank (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- LINC00910 | chr17:43381295 C>T | 3'Flank (SNP) | VAF 33/304 reads (11%) | called by muse, mutect2, varscan2
- OR52B1P | n.625G>C | RNA (SNP) | VAF 32/316 reads (10%) | called by muse, mutect2, varscan2
